Somatic mutation profile of tumor specimen TCGA-BS-A0UL-01A (aliquot TCGA-BS-A0UL-01A-11D-A10G-09) from TCGA case TCGA-BS-A0UL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 54.7 years (19,982 days).
Specimen TCGA-BS-A0UL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f74dc108-23df-449c-b96d-169c8186361c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UL-10A (Blood Derived Normal), aliquot TCGA-BS-A0UL-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8527198-efc2-4308-92da-ade6f97a9881

The open-access MAF lists 464 somatic variants for this specimen: 353 protein-altering or splice-affecting, 100 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 100, Frame Shift Del 58, Nonsense Mutation 20, Frame Shift Ins 13, Intron 7, Splice Region 3, In Frame Del 2, Splice Site 2, In Frame Ins 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 42/207 reads (20%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- AMPD1 | c.1893A>T p.L631F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200717164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as rs55861249, CM960096, COSV53734495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- F9 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | catalogued as rs137852261, CM940671, COSV54378604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/168 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ABCA12 | c.5891T>C p.I1964T (on ENST00000272895 / NM_173076.3; = p.I1646T on NM_015657.3) | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.253); catalogued as COSV55953420; called by muse, mutect2, varscan2
- ABCA8 | c.1926G>A p.A642= | Splice Region (SNP) | VAF 20/138 reads (14%) | catalogued as rs1008889375, COSV52196681; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as rs757016425; called by mutect2, varscan2
- ACKR3 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV56021043; called by muse, mutect2, varscan2
- ACO1 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1182113291, COSV59378437; called by muse, mutect2, varscan2
- ACOT11 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59347105, COSV59347390; called by mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ACTL6A | c.769T>C p.C257R | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as rs374221322; called by muse, mutect2, varscan2
- ADAM30 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65560647; called by muse, mutect2, varscan2
- ADAMTS12 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as rs768135654, COSV61258812; called by muse, mutect2, varscan2
- ADAMTS19 | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV50737156; called by muse, mutect2, varscan2
- ADAMTS4 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs767544003, COSV63489281; called by muse, mutect2, varscan2
- ADCK1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV53079311; called by muse, mutect2, varscan2
- ADRA1B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571519472, COSV60701056; called by muse, mutect2, varscan2
- AHNAK | c.14027T>C p.L4676P | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142267795; called by muse, mutect2
- AKAP17A | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV58308942; called by muse, mutect2, varscan2
- AKAP3 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs775740904, COSV57415208; called by muse, varscan2
- ALMS1 | c.4394C>T p.T1465M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs200980776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | catalogued as COSV55045015, COSV99781251; called by muse, mutect2, varscan2
- ANKEF1 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs752017095, COSV65692119; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1167249334, COSV51843805; called by muse, mutect2, varscan2
- ANKRD12 | c.1104T>A p.D368E | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1352666774, COSV50820928; called by muse, mutect2, varscan2
- ANKRD13C | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52030639; called by muse, mutect2, varscan2
- ANKRD52 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV57283307; called by muse, mutect2, varscan2
- ANO8 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50174383; called by muse, mutect2, varscan2
- AP4M1 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs1411282854, COSV57995030; called by muse, mutect2, varscan2
- ARHGAP35 | c.4073A>C p.K1358T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV68329953; called by muse, mutect2, varscan2
- ASMTL | c.732del p.G245Afs*47 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1438753766, COSV67243140; called by mutect2, varscan2
- ASTE1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284748949, COSV53908117; called by muse, mutect2, varscan2
- ATG2B | c.4396G>A p.G1466S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752638073, COSV55889843; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV57748303; called by muse, mutect2, varscan2
- ATRNL1 | c.2048G>A p.C683Y | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV61800348; called by muse, mutect2, varscan2
- B4GALT2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765252809, COSV52542941; called by muse, mutect2, varscan2
- BAZ2A | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs775297286, COSV51632740; called by muse, mutect2, varscan2
- BDP1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs750016343, COSV62430268; called by muse, mutect2, varscan2
- BTRC | c.1784C>T p.S595F (on ENST00000370187 / NM_033637.4; = p.S559F on NM_003939.5) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs776181591, COSV64579117; called by muse, mutect2, varscan2
- C1orf146 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV64880216; called by muse, mutect2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CALD1 | c.1585del p.Q529Rfs*76 (on ENST00000361675 / NM_033138.4; = p.Q274Rfs*76 on NM_004342.7) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1554474721; called by mutect2, pindel, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAPN1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs377052700; called by muse, mutect2, varscan2
- CCDC60 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59541844; called by muse, mutect2
- CCNJ | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as rs1441815922, COSV56442349; called by muse, mutect2, varscan2
- CDC37L1 | c.981_983del p.E327del | In Frame Del (DEL) | VAF 56/290 reads (19%) | catalogued as rs1323749373; called by pindel, varscan2
- CDC42BPA | c.132T>A p.N44K | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV62007624; called by muse, mutect2, varscan2
- CDH12 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV66394816; called by muse, mutect2, varscan2
- CDH23 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs747334403, COSV56454204; called by muse, mutect2, varscan2
- CDH23 | c.4505G>A p.R1502Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as rs774355776, COSV56454215; called by muse, mutect2, varscan2
- CEP170 | c.3616A>T p.I1206F | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV60507488; called by muse, mutect2, varscan2
- CERS2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV54979437; called by muse, mutect2
- CHD3 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745707523, COSV57873546; called by muse, mutect2, varscan2
- CHMP1B | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52324923; called by muse, mutect2, varscan2
- CHUK | c.1193T>C p.F398S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.574); catalogued as COSV64917523; called by muse, mutect2
- CLCN6 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV56738920; called by muse, mutect2, varscan2
- CLCNKB | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as rs140538259; called by muse, mutect2, varscan2
- CLDN15 | c.70_71del p.L24Afs*27 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | catalogued as rs1012108761; called by pindel, varscan2
- CLTCL1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs563436981, COSV54227309, COSV99594550; called by muse, mutect2, varscan2
- CNKSR2 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54252247; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs374805044; called by mutect2, varscan2
- COL5A1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs142933609, COSV65667254; called by muse, mutect2, varscan2
- CPA3 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750672324, COSV56044375; called by muse, mutect2
- CRHBP | c.282_283insTGG p.T94_I95insW | In Frame Ins (INS) | VAF 5/27 reads (19%) | catalogued as COSV57187904; called by mutect2, pindel*
- CRYBB1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs777514223, COSV53232803; called by muse, mutect2, varscan2
- CTDSPL2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1477816940, COSV52945400; called by muse, mutect2, varscan2
- CTHRC1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57715158, COSV57715243; called by muse, mutect2, varscan2
- CTR9 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV63728161; called by muse, mutect2, varscan2
- CUL4B | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as COSV60685880; called by muse, mutect2, varscan2
- CYP2R1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782520338, COSV58126950; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DAZAP1 | c.925del p.V309Ffs*26 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as COSV51833062; called by mutect2, pindel, varscan2
- DCAF12L1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs748351807, COSV64421400, COSV64421892; called by muse, mutect2, varscan2
- DCAF6 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV56576687; called by muse, mutect2, varscan2
- DCAF7 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV60406710; called by muse, mutect2
- DCHS1 | c.7549G>A p.A2517T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs769541938, COSV54996671; called by muse, mutect2, varscan2
- DDR2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs767283136, COSV63370128; called by muse, mutect2, varscan2
- DDX24 | c.893T>C p.L298S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV58212067; called by muse, mutect2, varscan2
- DDX5 | c.1477C>A p.R493S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV56748499, COSV56750795; called by muse, mutect2, varscan2
- DLG2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54631130, COSV99714552; called by muse, mutect2, varscan2
- DNAH2 | c.10126G>A p.A3376T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs751113038, COSV66718002; called by muse, mutect2, varscan2
- DNAH5 | c.13485G>A p.M4495I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1424487626, COSV54213473; called by muse, mutect2, varscan2
- DNAI1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54279872; called by muse, mutect2, varscan2
- DNAI1 | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV54279881; called by muse, mutect2, varscan2
- DNM2 | c.2308C>T p.R770* (on ENST00000355667 / NM_001005360.3; = p.R766* on NM_004945.3) | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV53033391; called by muse, mutect2, varscan2
- DTL | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65341998; called by muse, mutect2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- E2F2 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs141515224; called by muse, mutect2, varscan2
- EBF1 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV58172446; called by muse, varscan2
- EMC1 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV64345484; called by muse, mutect2, varscan2
- EPHA4 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56029168; called by muse, mutect2, varscan2
- ERN1 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761854769, COSV70501162; called by muse, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 90/554 reads (16%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXOC4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs775034999, COSV54089612; called by muse, mutect2, varscan2
- FAM217A | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV51159330; called by muse, mutect2, varscan2
- FAM234A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs759550507, COSV56993148; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FAR2 | c.190C>T p.L64= | Splice Region (SNP) | VAF 35/253 reads (14%) | catalogued as COSV51724452; called by muse, mutect2, varscan2
- FAT3 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs528757478, COSV53091298; called by muse, mutect2, varscan2
- FGD3 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61596378; called by muse, mutect2, varscan2
- FGFR1 | c.2452G>A p.G818R (on ENST00000447712 / NM_023110.3; = p.G816R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.129); catalogued as rs17182456; called by muse, mutect2, varscan2
- FMR1NB | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs868988926, COSV65071402; called by muse, mutect2, varscan2
- FSCB | c.440del p.P147Lfs*2 | Frame Shift Del (DEL) | VAF 43/202 reads (21%) | catalogued as COSV61219806; called by mutect2, pindel, varscan2
- GABRG2 | c.863C>T p.T288I (on ENST00000361925 / NM_001375343.1; = p.T248I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV62716487; called by muse, mutect2, varscan2
- GALNT17 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.339); catalogued as COSV61153980, COSV61188172; called by muse, mutect2, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 33/193 reads (17%) | catalogued as rs782212939; called by mutect2, pindel, varscan2
- GATAD2A | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV53068100; called by muse, mutect2, varscan2
- GATAD2B | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV64083666; called by muse, mutect2, varscan2
- GCNA | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs761245998, COSV65466226; called by muse, mutect2, varscan2
- GDPD5 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as COSV61126866; called by muse, mutect2, varscan2
- GGT1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs201448447, COSV50638897; called by muse, mutect2, varscan2
- GNA13 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762741889, COSV71474537; called by muse, mutect2, varscan2
- GON4L | c.4115C>T p.T1372M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs762760202, COSV55190197; called by muse, mutect2, varscan2
- GPR12 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV67344168; called by muse, mutect2, varscan2
- GPX8 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs961396571, COSV57050903; called by muse, mutect2, varscan2
- GRIP1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54019006; called by muse, mutect2, varscan2
- GSE1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); catalogued as COSV53670639; called by muse, mutect2, varscan2
- GSPT2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV61213930; called by muse, mutect2, varscan2
- HAVCR1 | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59398789; called by muse, mutect2, varscan2
- HCFC1 | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV60070589; called by muse, mutect2, varscan2
- HCN3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs763457688, COSV64233550; called by muse, mutect2, varscan2
- HECTD4 | c.8062C>T p.R2688C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1566072597, COSV66389048; called by muse, mutect2, varscan2
- HTR1B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.012); catalogued as COSV64051085; called by muse, mutect2, varscan2
- HTR5A | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs371458123; called by muse, mutect2, varscan2
- HYDIN | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55480919; called by muse, mutect2, varscan2
- IGF2R | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs371705752; called by muse, mutect2, varscan2
- IKBKE | c.1908G>T p.Q636H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV65623059; called by muse, mutect2, varscan2
- IL11RA | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs777601555, COSV52404677, COSV99426385; called by muse, mutect2, varscan2
- IL24 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs765575411, COSV54320210; called by muse, mutect2, varscan2
- IMPA2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374103594; called by muse, mutect2, varscan2
- ISG15 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65106467; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITLN1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV58274640; called by muse, mutect2
- ITPR1 | c.3713C>T p.A1238V (on ENST00000354582; = p.A1223V on NM_002222.7) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1195918323, COSV56967742; called by muse, mutect2, varscan2
- KCNA5 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229050065, COSV52904629, COSV52908015; called by muse, mutect2, varscan2
- KCND1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557058455, COSV54413180; called by muse, mutect2, varscan2
- KCNJ12 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs144639343; called by muse, mutect2
- KCNJ4 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1301496832, COSV57856544; called by muse, mutect2, varscan2
- KCNT1 | c.1333C>T p.R445C (on ENST00000488444; = p.R464C on NM_020822.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1564367281, COSV53698583, COSV53701081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5C | c.3158G>A p.G1053D | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.864); catalogued as rs1556835984, COSV64763732; called by muse, mutect2, varscan2
- KIAA0100 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1159681470, COSV66491443; called by muse, mutect2, varscan2
- KIAA1328 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV54450295; called by muse, mutect2, varscan2
- KIF11 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs754165708, COSV53268854; called by muse, mutect2, varscan2
- KIF1A | c.4567C>T p.R1523W (on ENST00000320389 / NM_001379639.1; = p.R1515W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs368124753; called by muse, mutect2, varscan2
- KIF21A | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.202); catalogued as COSV62768966; called by muse, mutect2, varscan2
- KIF26B | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs770007495, COSV63639090; called by muse, mutect2, varscan2
- KIF4A | c.3457A>G p.S1153G | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV65532479; called by muse, mutect2, varscan2
- LAMA5 | c.7936G>A p.V2646M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV53356000; called by muse, mutect2
- LAMB2 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567153631, COSV59730579; called by muse, mutect2, varscan2
- LIPH | c.449T>C p.M150T | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV56183286; called by muse, mutect2, varscan2
- LNX1 | c.1195C>T p.R399C (on ENST00000263925 / NM_001126328.3; = p.R303C on NM_032622.2) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs374285786; called by muse, mutect2, varscan2
- LRP2 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV55546724; called by muse, mutect2, varscan2
- LRRIQ3 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV63042304; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 70/346 reads (20%) | catalogued as rs752439249; called by mutect2, varscan2
- MACO1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs1212372275, COSV65475864; called by muse, mutect2, varscan2
- MADCAM1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1371295949, COSV53128017; called by muse, varscan2
- MAPKBP1 | c.3110C>T p.A1037V (on ENST00000456763 / NM_001128608.2; = p.A1031V on NM_014994.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV52959443; called by muse, mutect2, varscan2
- MAST1 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52243664; called by muse, mutect2, varscan2
- MCAT | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); catalogued as rs202009673, COSV51792136; called by muse, mutect2, varscan2
- MEPCE | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52768890; called by muse, mutect2
- MERTK | c.1775T>A p.I592N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV54926800; called by muse, mutect2, varscan2
- MET | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs764052874, COSV59258977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD6L | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV61002316; called by muse, mutect2, varscan2
- MINDY3 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1454592234, COSV53219243; called by muse, mutect2, varscan2
- MMP17 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs745545673, COSV62178770; called by muse, mutect2, varscan2
- MRPL39 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as rs756456682, COSV56260305; called by muse, mutect2, varscan2
- MXI1 | c.121del p.R41Dfs*11 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | catalogued as rs1564709409; called by mutect2, pindel, varscan2
- MYH2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 51/332 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs267604724, COSV55432215; called by muse, mutect2, varscan2
- MYO1G | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs554354933, COSV51853066; called by muse, mutect2, varscan2
- MYO1H | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375026737; called by muse, mutect2, varscan2
- MYOM1 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs747613137, COSV55286982; called by muse, mutect2, varscan2
- NBPF20 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 26/266 reads (10%) | catalogued as rs1553665948; called by muse, mutect2, varscan2
- NKRF | c.98A>G p.H33R | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV58661080; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 26/292 reads (9%) | catalogued as COSV69407880; called by mutect2, pindel
- NMNAT3 | c.190C>T p.R64* (on ENST00000296202 / NM_001320512.1; = p.R27* on NM_178177.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | catalogued as rs201923390, COSV56155493, COSV56156281; called by muse, mutect2, varscan2
- NMUR1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV59403808; called by muse, mutect2, varscan2
- NR3C1 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as COSV51541319; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 19/100 reads (19%) | catalogued as rs780417788; called by mutect2, varscan2
- NXPE3 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs761784698, COSV56289152; called by muse, mutect2, varscan2
- OR10T2 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV57780635; called by muse, mutect2, varscan2
- OR14C36 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs375345809; called by muse, mutect2, varscan2
- OR2M5 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs377460924; called by muse, mutect2, varscan2
- OR6C65 | c.465del p.V158* | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | catalogued as rs1403510488; called by mutect2, pindel, varscan2
- OS9 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs773887597, COSV57781987; called by muse, mutect2, varscan2
- OXER1 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as rs1410827986, COSV54310269; called by muse, mutect2
- PAQR6 | c.646C>T p.Q216* (on ENST00000292291 / NM_001272108.2; = p.Q110* on NM_024897.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52744623; called by muse, mutect2, varscan2
- PCDHA13 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV56487670; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs782213177; called by mutect2, pindel, varscan2
- PCK1 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745817666, COSV60126944; called by muse, mutect2, varscan2
- PDIA6 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV55349444, COSV55349941; called by muse, mutect2, varscan2
- PDXDC1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as rs751031747, COSV57905142; called by muse, mutect2, varscan2
- PDZK1IP1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV53743938; called by muse, mutect2, varscan2
- PHF19 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.769); catalogued as rs1420408691, COSV65877631; called by muse, mutect2, varscan2
- PIKFYVE | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs891262232, COSV100010811, COSV52238895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKDREJ | c.4004T>A p.V1335D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53547592; called by muse, mutect2, varscan2
- PLA2R1 | c.3287G>A p.C1096Y | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51776588; called by muse, mutect2, varscan2
- PLCD1 | c.1946A>T p.N649I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV52183313; called by muse, mutect2, varscan2
- PLEC | c.2686C>T p.R896W (on ENST00000322810 / NM_201380.4; = p.R786W on NM_000445.5) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781846297, COSV59617142; called by muse, mutect2, varscan2
- PLXNA1 | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs748301984, COSV52523949; called by muse, mutect2, varscan2
- PLXNA4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as rs762255363, COSV58109128; called by muse, mutect2, varscan2
- PODN | c.1433G>A p.R478H (on ENST00000395871; = p.R430H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs146352896; called by muse, mutect2, varscan2
- POLR2C | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.545); catalogued as rs577175555, COSV54671734; called by muse, mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- PPFIA2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as rs200410799, COSV61025497; called by muse, mutect2, varscan2
- PRICKLE1 | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV61542519, COSV61544058; called by muse, mutect2
- PRKACG | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55244618; called by muse, mutect2, varscan2
- PRKD1 | c.2620G>A p.G874S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV59562720; called by muse, mutect2, varscan2
- PROM2 | c.1773C>A p.D591E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV58297433; called by muse, mutect2, varscan2
- PSD3 | c.2381G>T p.R794L (on ENST00000440756; = p.R793L on NM_015310.4) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54068829, COSV54076333; called by muse, mutect2, varscan2
- PSTPIP1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375063664; called by muse, mutect2, varscan2
- PTBP2 | c.46G>A p.V16I (on ENST00000426398 / NM_001300986.2; = p.V8I on NM_021190.4) | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as COSV64623959; called by muse, mutect2, varscan2
- RAD54B | c.1770del p.K590Nfs*13 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs1457376007; called by mutect2, pindel, varscan2
- RASGRF2 | c.2603C>T p.T868M | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs752271804, COSV54126279; called by muse, mutect2, varscan2
- RBFOX2 | c.462+1G>A p.X154_splice (on ENST00000438146 / NM_001349995.2; = p.X84_splice on NM_014309.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 60/318 reads (19%) | catalogued as COSV53263611; called by muse, varscan2
- RBM10 | c.2645A>G p.Q882R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61308392; called by muse, mutect2, varscan2
- REXO1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV50075862; called by muse, mutect2, varscan2
- REXO1 | c.201dup p.A68Rfs*34 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | catalogued as rs759731898; called by mutect2, varscan2
- RFWD3 | c.2073del p.F691Lfs*9 | Frame Shift Del (DEL) | VAF 40/237 reads (17%) | catalogued as rs867228258; called by mutect2, pindel, varscan2
- RNASEH2A | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs1568386885, COSV55551483; called by muse, mutect2, varscan2
- RNF152 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777722574, COSV57183714; called by muse, mutect2, varscan2
- RNF2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV62279122; called by muse, mutect2
- RNF213 | c.12056G>A p.R4019H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs752629050, COSV60393579; called by muse, mutect2, varscan2
- RNF32 | c.199del p.T67Lfs*7 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as rs771776056; called by mutect2, pindel
- ROBO4 | c.2951A>G p.Q984R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60622598; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL5 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV59873219; called by muse, mutect2, varscan2
- RPS6KA3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.793); catalogued as COSV65387285; called by muse, mutect2, varscan2
- RSBN1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs750349807, COSV54731624; called by muse, mutect2, varscan2
- RTTN | c.3655C>G p.L1219V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV55342859; called by muse, mutect2, varscan2
- RYR1 | c.10885C>T p.R3629W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1434232361, COSV62091161, COSV62092451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.12677C>T p.P4226L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1324957330, COSV63660059; called by muse, mutect2, varscan2
- SAE1 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV54294026; called by muse, mutect2, varscan2
- SALL2 | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs767070558, COSV100444409; called by muse, mutect2
- SCD5 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs199983077, COSV56725207; called by muse, mutect2, varscan2
- SEPTIN5 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV63530487; called by muse, mutect2, varscan2
- SET | c.296T>G p.F99C (on ENST00000372692 / NM_001374326.1; = p.F86C on NM_003011.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59001517; called by muse, mutect2, varscan2
- SHANK3 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764037844, COSV53185165, COSV99436551; called by muse, mutect2, varscan2
- SIGLEC1 | c.954dup p.I319Hfs*9 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | catalogued as rs765529239; called by mutect2, pindel
- SLC12A7 | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV53755693; called by muse, mutect2, varscan2
- SLC18B1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV51593786; called by muse, mutect2
- SLC26A5 | c.410T>A p.F137Y | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as COSV59699688; called by muse, mutect2, varscan2
- SLC28A1 | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs763284132, COSV54477627; called by muse, mutect2, varscan2
- SLC2A9 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53316033, COSV53318486; called by muse, mutect2, varscan2
- SLC35D3 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as rs1358697670, COSV59377585; called by muse, mutect2, varscan2
- SLC39A5 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756666376, COSV57191033; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs747319777; called by mutect2, varscan2
- SLX4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs147872182; called by muse, mutect2, varscan2
- SNTG1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 36/194 reads (19%) | catalogued as COSV52433296; called by muse, varscan2
- SNX19 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56284681; called by muse, mutect2, varscan2
- SP2 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV65063672; called by muse, mutect2
- SPATA7 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs545998461, COSV50416364; called by muse, mutect2, varscan2
- SPDYA | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs139604395; called by muse, mutect2, varscan2
- SPNS3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as rs1450622062, COSV61069538; called by muse, mutect2, varscan2
- SPSB1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs971482356, COSV60162655; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | PolyPhen probably damaging (0.917); catalogued as rs1475566953, COSV59561973; called by muse, mutect2
- STX5 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as rs766883173, COSV53678629; called by muse, mutect2, varscan2
- STXBP4 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV64464123; called by muse, mutect2, varscan2
- SUGP2 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58256682; called by muse, mutect2, varscan2
- TAB3 | c.1613A>G p.E538G | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1197127495, COSV55835444; called by muse, mutect2, varscan2
- TBC1D1 | c.2904del p.W969Gfs*15 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | catalogued as COSV54721959; called by mutect2, pindel, varscan2
- TF | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV53919032; called by muse, mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs544132101; called by mutect2, varscan2
- THBS1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1347334087, COSV52950931; called by muse, mutect2, varscan2
- TIMM22 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 92/450 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1176871824, COSV56831860; called by muse, mutect2, varscan2
- TIMP3 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs764214887, COSV56662765, COSV99831270; called by muse, mutect2, varscan2
- TLCD5 | c.215C>A p.P72H (on ENST00000375095 / NM_001198671.2; = p.P94H on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV58754780; called by muse, mutect2, varscan2
- TMEM171 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs137882806, COSV55129617; called by muse, mutect2, varscan2
- TMPRSS11A | c.143del p.K48Rfs*11 | Frame Shift Del (DEL) | VAF 40/266 reads (15%) | catalogued as rs763235501; called by mutect2, varscan2
- TNPO2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs778630699, COSV63507859; called by muse, mutect2, varscan2
- TNRC6A | c.2696del p.G899Efs*4 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV59362326; called by mutect2, pindel, varscan2
- TRANK1 | c.6013G>A p.A2005T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV57145272; called by muse, mutect2, varscan2
- TRERF1 | c.1930C>A p.P644T | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV61668964; called by muse, mutect2
- TRIM42 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV53881076; called by muse, mutect2, varscan2
- UBA1 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556787688, COSV60111883; called by muse, mutect2, varscan2
- UBA1 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV100255638, COSV60111897; called by muse, mutect2, varscan2
- UBXN1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs773227855, COSV53656696; called by muse, mutect2
- UFL1 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as rs780680640, COSV65149619, COSV65150537; called by muse, mutect2, varscan2
- UPF1 | c.3346C>T p.R1116W (on ENST00000599848 / NM_001297549.2; = p.R1105W on NM_002911.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53194674; called by muse, mutect2, varscan2
- USP30 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 66/382 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs1378909983, COSV57448716; called by muse, mutect2, varscan2
- USP45 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs749684555, COSV57328225; called by muse, mutect2, varscan2
- USP47 | c.1330A>G p.S444G (on ENST00000399455 / NM_001372095.1; = p.S356G on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV60462102; called by muse, mutect2, varscan2
- USP47 | c.3283G>A p.V1095I (on ENST00000399455 / NM_001372095.1; = p.V1007I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs571949588, COSV59693966; called by muse, varscan2
- UVRAG | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV62102518; called by mutect2, varscan2
- VARS2 | c.838T>A p.S280T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52558251; called by muse, mutect2
- VAV1 | c.2405C>T p.S802L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58381191; called by muse, mutect2, varscan2
- WDR1 | c.677C>T p.A226V (on ENST00000382452; = p.A86V on NM_005112.5) | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs781406373, COSV66723639; called by muse, mutect2, varscan2
- WDR72 | c.2926T>C p.S976P | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as COSV64743321; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK3 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192392222, COSV63612715; called by muse, mutect2, varscan2
- WWC1 | c.2789T>C p.F930S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1382816988, COSV54648654; called by muse, mutect2, varscan2
- XIRP2 | c.5021G>A p.S1674N (on ENST00000628543; = p.S1849N on NM_152381.6) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV54689617; called by muse, mutect2
- ZBTB11 | c.283T>A p.Y95N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV57244461; called by muse, mutect2, varscan2
- ZBTB3 | c.650T>A p.V217D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV67361038; called by muse, mutect2, varscan2
- ZC3H10 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1020250115, COSV57768561; called by muse, mutect2, varscan2
- ZCCHC24 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64886408; called by muse, mutect2, varscan2
- ZEB2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs975397942, COSV57953916, COSV57956804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAT | c.2243-3del | Splice Region (DEL) | VAF 7/32 reads (22%) | catalogued as rs35184160; called by mutect2, pindel, varscan2
- ZMAT1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 102/539 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs377073155, COSV65658061; called by muse, mutect2, varscan2
- ZMYM2 | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 34/190 reads (18%) | catalogued as COSV67033080; called by muse, mutect2, varscan2
- ZMYM3 | c.1195del p.Q399Sfs*48 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as COSV58741170; called by mutect2, pindel, varscan2
- ZNF205 | c.1085A>T p.K362M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54620371; called by muse, mutect2, varscan2
- ZNF3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1342225160, COSV52795443; called by muse, mutect2, varscan2
- ZNF319 | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.725); catalogued as COSV54621610; called by mutect2, varscan2
- ZNF43 | c.870A>T p.E290D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV61683362; called by muse, mutect2, varscan2
- ZNF43 | c.702A>T p.E234D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); catalogued as COSV61683005; called by muse, mutect2, varscan2
- ZNF540 | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV57108617; called by muse, mutect2, varscan2
- ZNF600 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs747468038, COSV57741973; called by muse, mutect2, varscan2
- ZXDA | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62387731; called by muse, mutect2, varscan2
- ZZEF1 | c.5666G>T p.R1889M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67556714; called by muse, mutect2, varscan2
- APLP1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2
- ARID5B | c.1326del p.K442Nfs*37 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- ATXN1 | c.719del p.P240Hfs*37 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- CAST | c.1259del p.P420Lfs*6 (on ENST00000341926; = p.P503Lfs*6 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- CHD6 | c.6033del p.T2012Hfs*85 | Frame Shift Del (DEL) | VAF 37/210 reads (18%) | called by mutect2, pindel, varscan2
- CIC | c.3347del p.P1116Qfs*45 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.2786del p.G929Afs*12 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- DCAF8L1 | c.954dup p.D319Rfs*14 | Frame Shift Ins (INS) | VAF 33/222 reads (15%) | called by mutect2, pindel, varscan2
- DDX50 | c.1017del p.K339Nfs*3 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.890del p.P297Rfs*13 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | called by mutect2, pindel, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- ECE1 | c.1779del p.K594Rfs*3 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- EEF2 | c.124_127dup p.A43Efs*17 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- FNBP4 | c.2846dup p.W950Vfs*7 | Frame Shift Ins (INS) | VAF 43/255 reads (17%) | called by mutect2, pindel, varscan2
- FRK | c.1387del p.Y463Tfs*42 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- GANAB | c.1348dup p.R450Pfs*5 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- GPR179 | c.3869del p.K1290Rfs*12 (on ENST00000621958; = p.K1289Rfs*12 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- HIP1R | c.1032del p.N345Mfs*4 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- INO80 | c.1879dup p.V627Gfs*27 | Frame Shift Ins (INS) | VAF 6/70 reads (9%) | called by mutect2, pindel
- KDM3B | c.4925del p.P1642Lfs*36 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | called by mutect2, pindel, varscan2
- LCT | c.5168_5170del p.K1723del | In Frame Del (DEL) | VAF 34/127 reads (27%) | called by mutect2, pindel, varscan2
- LRP1 | c.5716dup p.L1906Pfs*5 | Frame Shift Ins (INS) | VAF 27/130 reads (21%) | called by mutect2, pindel, varscan2
- MED25 | c.1448_1449del p.L483Qfs*24 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- MRM1 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- MYH7 | c.2538_2539del p.K847Gfs*39 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by pindel, varscan2
- NLRC4 | c.270del p.H91Ifs*15 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- NR4A2 | c.325del p.Q109Sfs*5 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, varscan2
- PRELP | c.242del p.P81Lfs*61 | Frame Shift Del (DEL) | VAF 33/176 reads (19%) | called by mutect2, pindel, varscan2
- PTPRE | c.488del p.N163Tfs*14 | Frame Shift Del (DEL) | VAF 32/188 reads (17%) | called by mutect2, pindel, varscan2
- REV3L | c.9135_9136del p.C3045* | Nonsense Mutation (DEL) | VAF 27/151 reads (18%) | called by pindel, varscan2
- SCN10A | c.5825del p.N1942Mfs*10 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- SIK3 | c.2048del p.M684Wfs*84 (on ENST00000445177 / NM_001366686.2; = p.M642Wfs*84 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- STPG3 | c.286dup p.L96Pfs*5 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TAF3 | c.1461del p.N488Tfs*34 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- THAP12 | c.355del p.I119Lfs*37 | Frame Shift Del (DEL) | VAF 89/429 reads (21%) | called by mutect2, pindel, varscan2
- UBR5 | c.6360dup p.E2121Rfs*13 | Frame Shift Ins (INS) | VAF 47/292 reads (16%) | called by mutect2, varscan2
- ZNF292 | c.3938del p.G1313Vfs*12 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- AC136428.1 | c.330G>A p.T110= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs1394520550, COSV71169080; called by muse, mutect2, varscan2
- ADAMTS20 | c.3360T>C p.A1120= | Silent (SNP) | VAF 44/229 reads (19%) | catalogued as COSV67129250; called by muse, mutect2, varscan2
- AGT | c.396C>A p.T132= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV64184172; called by muse, mutect2, varscan2
- ALS2 | c.528C>T p.T176= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs35097965; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP2 | c.1257A>G p.E419= | Silent (SNP) | VAF 10/179 reads (6%) | catalogued as COSV58284463; called by muse, mutect2
- ARFGEF3 | c.2358T>C p.I786= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV52453701; called by muse, mutect2, varscan2
- ARL2 | c.252C>T p.T84= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs771266504, COSV55861004; called by muse, mutect2, varscan2
- ASB7 | c.207C>T p.H69= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs906024155, COSV58403489; called by muse, mutect2, varscan2
- ASIC1 | c.186G>A p.T62= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs61735039, COSV57316837; called by muse, mutect2, varscan2
- B3GNT9 | c.552C>T p.A184= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV54625375, COSV54626487; called by muse, mutect2, varscan2
- C9orf131 | c.13C>T p.L5= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56610142; called by muse, mutect2, varscan2
- CACNA1G | c.3087G>A p.P1029= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs746507592, COSV61722575; called by muse, mutect2
- CCDC110 | c.1959T>C p.A653= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV56870038; called by muse, mutect2, varscan2
- CD19 | c.15C>A p.R5= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs748727571; called by muse, mutect2
- CHRNA7 | c.960C>T p.H320= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs753933393, COSV60968830; called by muse, mutect2, varscan2
- CHSY1 | c.843C>T p.Y281= | Silent (SNP) | VAF 47/207 reads (23%) | catalogued as rs181121069; called by muse, mutect2, varscan2
- CLPP | c.627C>T p.Y209= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as rs750783628, COSV55536308; called by muse, mutect2, varscan2
- CLUH | c.3783G>A p.A1261= (on ENST00000435359; = p.A1300= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs763111938, COSV70928275; called by muse, mutect2, varscan2
- CSPG4 | c.2949T>C p.D983= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs374361253; called by muse, mutect2
- DNAH3 | c.11412C>T p.N3804= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as rs776613491, COSV54511411; called by muse, mutect2, varscan2
- DTWD1 | c.789T>C p.T263= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV52071343; called by muse, mutect2, varscan2
- DZIP1L | c.1797C>A p.P599= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV59519825; called by muse, mutect2, varscan2
- FAM161A | c.699G>A p.V233= | Silent (SNP) | VAF 69/392 reads (18%) | catalogued as rs994005901, COSV56765021; called by muse, mutect2, varscan2
- FBN2 | c.3075C>T p.C1025= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV52502968; called by muse, mutect2, varscan2
- FBXL18 | c.2052C>T p.H684= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs190326632; called by muse, mutect2, varscan2
- FBXO24 | c.1189C>A p.R397= (on ENST00000241071 / NM_033506.3; = p.R435= on NM_012172.5) | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV53824778, COSV53829884; called by muse, mutect2, varscan2
- FER1L5 | c.3972A>G p.T1324= (on ENST00000623019; = p.T1297= on NM_001293083.2) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV67605886; called by muse, mutect2, varscan2
- GPR155 | c.1371C>A p.T457= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV55038098; called by muse, mutect2, varscan2
- H1-1 | c.342G>A p.A114= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as COSV55119008; called by muse, mutect2, varscan2
- HEXA | c.300C>T p.V100= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV51505739; called by muse, mutect2, varscan2
- HIRA | c.570T>C p.A190= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs1335711523, COSV54273494; called by muse, mutect2
- HIVEP1 | c.3990G>A p.T1330= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs763551721, COSV65099919; called by muse, mutect2, varscan2
- HSPA2 | c.159C>T p.G53= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs150693771; called by muse, mutect2, varscan2
- HUNK | c.1872C>T p.H624= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs376197217, COSV54226079; called by muse, mutect2, varscan2
- INHBA | c.123C>T p.A41= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54220396, COSV99638110; called by muse, mutect2, varscan2
- IQSEC2 | c.2205G>A p.Q735= (on ENST00000642864 / NM_001111125.3; = p.Q530= on NM_015075.2) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV64724467; called by muse, mutect2, varscan2
- KANK1 | c.1983C>T p.A661= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs763629960, COSV63211105; called by muse, mutect2
- KATNIP | c.4839G>A p.T1613= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs746502962, COSV55176390; called by muse, mutect2, varscan2
- KIRREL1 | c.1660C>A p.R554= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV63286019; called by muse, mutect2, varscan2
- KLB | c.897G>A p.T299= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1028208417, COSV57300813; called by muse, mutect2, varscan2
- KRT85 | c.240C>T p.F80= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs778706364, COSV57736391; called by muse, mutect2
- LAS1L | c.1110T>C p.N370= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56706750; called by muse, mutect2, varscan2
- MAN2B2 | c.2862G>A p.S954= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs368776410; called by muse, mutect2, varscan2
- MARK2 | c.2223C>T p.G741= (on ENST00000402010 / NM_001039469.2; = p.G677= on NM_004954.5) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs994924151, COSV56849689; called by muse, mutect2, varscan2
- MCM3AP | c.2232G>A p.T744= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52437994; called by muse, mutect2, varscan2
- MLH1 | c.2100G>A p.Q700= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV51615939; called by muse, mutect2, varscan2
- NAGK | c.228C>T p.S76= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs767605324, COSV54903230; called by mutect2, varscan2
- NID2 | c.3090C>T p.Y1030= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs773630715, COSV53494408; called by muse, mutect2
- NKX2-2 | c.651G>A p.A217= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs113222063, COSV65819307; called by muse, mutect2
- NLRP11 | c.1962T>C p.S654= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV64086391; called by muse, mutect2
- NUP210 | c.5532G>A p.T1844= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1336854679, COSV54404291; called by muse, mutect2, varscan2
- OLIG3 | c.201C>T p.S67= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV62988388; called by muse, mutect2, varscan2
- PCDHA11 | c.1446C>T p.D482= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV56487661; called by muse, mutect2, varscan2
- PCDHA6 | c.1842G>A p.P614= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1554132408, COSV65343085; called by muse, mutect2, varscan2
- PCDHA9 | c.1785C>T p.R595= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV65324696; called by muse, mutect2, varscan2
- PCDHB1 | c.339G>A p.P113= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1372628933, COSV60630070; called by muse, mutect2, varscan2
- PCDHGB7 | c.735C>T p.D245= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs775489120, COSV53919190; called by muse, mutect2, varscan2
- PCGF5 | c.150C>T p.S50= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as COSV60237529; called by muse, mutect2, varscan2
- PDCD7 | c.1161A>G p.R387= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV52600039; called by muse, mutect2, varscan2
- PDIA6 | c.1003C>T p.L335= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs905637635, COSV55349923; called by muse, mutect2, varscan2
- PHIP | c.240T>C p.H80= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV51502713; called by muse, mutect2, varscan2
- PHLPP2 | c.3108T>C p.G1036= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV62423465; called by muse, mutect2, varscan2
- PIK3CD | c.1146C>T p.C382= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs746151747, COSV63127740; called by muse, mutect2, varscan2
- PKD2L2 | c.1683C>T p.N561= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV50365037; called by muse, mutect2, varscan2
- PKHD1 | c.1125G>A p.R375= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV61866947; called by muse, mutect2, varscan2
- PLPP3 | c.294C>T p.L98= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs750545999, COSV64838995; called by muse, mutect2, varscan2
- PRELID3B | c.561A>G p.A187= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as rs757738795, COSV54812428; called by muse, mutect2
- PRKCSH | c.342C>T p.N114= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV52950817; called by muse, mutect2, varscan2
- PRRC2B | c.5016C>T p.G1672= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1300207927, COSV57644750; called by muse, mutect2, varscan2
- PXDN | c.2559C>T p.N853= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs566474453, COSV53229670; called by muse, varscan2
- RHOXF1 | c.252G>A p.P84= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs782371792, COSV54294349; called by muse, mutect2
- RIPOR3 | c.2703C>T p.A901= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs376014995; called by muse, mutect2, varscan2
- RTN4RL1 | c.543C>T p.H181= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs774811344, COSV58675029; called by muse, mutect2, varscan2
- SERPINA3 | c.246C>T p.T82= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs756445395, COSV67585581; called by muse, mutect2, varscan2
- SIGLEC14 | c.501A>C p.P167= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV55778471; called by mutect2, varscan2
- SLC35G3 | c.159C>T p.F53= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV52010659; called by muse, mutect2, varscan2
- SLC6A12 | c.861G>A p.A287= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs202060928, COSV62883791, COSV62885546; called by muse, mutect2, varscan2
- SLCO3A1 | c.915C>T p.S305= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as rs367736458; called by muse, mutect2, varscan2
- SPATA31A1 | c.888A>G p.S296= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- STAG2 | c.1665A>G p.T555= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV54354278; called by muse, mutect2, varscan2
- STK11IP | c.1797G>A p.S599= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs768524783, COSV55246936; called by muse, mutect2, varscan2
- SUPT7L | c.501C>A p.A167= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61822594; called by muse, mutect2, varscan2
- TMEM147 | c.276C>T p.A92= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs571165424, COSV52866802; called by muse, mutect2, varscan2
- TNN | c.1911G>A p.T637= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs780062151, COSV53423626; called by muse, mutect2, varscan2
- TNRC6C | c.3567G>A p.A1189= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs570306461, COSV56940132; called by muse, mutect2, varscan2
- TOX3 | c.417C>T p.S139= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV54864357; called by muse, mutect2, varscan2
- TPRG1L | c.771C>T p.N257= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs147440838; called by muse, mutect2, varscan2
- TRAF3IP2 | c.690G>T p.V230= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV60675388; called by muse, mutect2, varscan2
- TRIM50 | c.333C>T p.C111= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1169046579, COSV52719392; called by muse, mutect2, varscan2
- TUBA3E | c.1341C>T p.G447= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as rs144218629; called by muse, mutect2, varscan2
- UBN1 | c.684C>T p.L228= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52166879; called by muse, varscan2
- UHRF1 | c.1692C>T p.Y564= (on ENST00000612630 / NM_001290050.1; = p.Y577= on NM_013282.4) | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs1226425195, COSV53573674; called by muse, mutect2, varscan2
- UNC13A | c.3885C>T p.N1295= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs539091973, COSV53191367; called by mutect2, varscan2
- VEGFB | c.132C>T p.R44= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs138244998; called by muse, mutect2, varscan2
- WLS | c.1353C>T p.I451= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs201544180, COSV52039203; called by muse, mutect2, varscan2
- YLPM1 | c.5280T>A p.G1760= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV53108732; called by muse, mutect2, varscan2
- ZDHHC5 | c.84G>A p.T28= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as rs757140213, COSV54705776; called by muse, mutect2, varscan2
- ZFYVE26 | c.3528T>C p.H1176= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV61325926; called by muse, mutect2, varscan2
- ZNF174 | c.702G>A p.V234= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs759530416, COSV51902324; called by muse, mutect2, varscan2
- ZNF274 | c.483C>T p.R161= (on ENST00000610905; = p.R56= on NM_016324.3) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58763600; called by muse, mutect2, varscan2
- AC005863.1 | n.390G>T | RNA (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- C9orf24 | c.*89G>A | 3'UTR (SNP) | VAF 23/118 reads (19%) | catalogued as rs778686715, COSV52624125; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2395T>C | Intron (SNP) | VAF 11/62 reads (18%) | catalogued as COSV56693809; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1358A>G | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56887880; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640672 C>T | 3'Flank (SNP) | VAF 11/48 reads (23%) | catalogued as COSV51704315; called by muse, mutect2, varscan2
- NRP2 | c.2440+9548C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as COSV55925241, COSV55929511; called by muse, mutect2, varscan2
- PRR12 | chr19:49594897 G>A | 5'Flank (SNP) | VAF 5/57 reads (9%) | catalogued as rs1022135369, COSV55869850, COSV55871751; called by muse, mutect2
- SGSM2 | c.1288+1979C>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs139683790; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2250G>A | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54095072; called by muse, mutect2, varscan2
- SMC4 | c.687+270C>T | Intron (SNP) | VAF 26/222 reads (12%) | catalogued as rs756199981, COSV61003856; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3354del | Intron (DEL) | VAF 23/135 reads (17%) | catalogued as rs767992187; called by mutect2, pindel, varscan2
